Somatic mutation profile of tumor specimen MP2PRT-PARCUW-TMP1-A (aliquot MP2PRT-PARCUW-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARCUW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,341 days).
Specimen MP2PRT-PARCUW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bbd9c57-f3fc-45ba-a9b5-97910f7d2d8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCUW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCUW-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2ffab98-eafb-40b8-b91b-8070d64404fa

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Nonsense Mutation 5, Intron 3, 5'UTR 2, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AZIN1 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 28/433 reads (6%) | catalogued as COSV61479745; called by muse, mutect2
- BECN1 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 41/471 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV59312461; called by muse, mutect2
- CAND2 | c.1954G>A p.E652K (on ENST00000456430 / NM_001162499.2; = p.E559K on NM_012298.3) | Missense Mutation (SNP) | VAF 27/506 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs755932293; called by muse, mutect2
- FAM126B | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 33/551 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV53772917; called by muse, mutect2
- ADAMTSL4 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 54/694 reads (8%) | called by muse, mutect2
- AKAP12 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2orf16 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2
- CRACD | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 34/566 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHX34 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 27/583 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- DOCK1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 139/319 reads (44%) | called by muse, mutect2, varscan2
- DST | c.11336T>G p.I3779R (on ENST00000361203 / NM_001374722.1; = p.I1367R on NM_015548.5) | Missense Mutation (SNP) | VAF 152/307 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- EDA2R | c.781A>T p.K261* | Nonsense Mutation (SNP) | VAF 60/747 reads (8%) | called by muse, mutect2
- HUWE1 | c.7112G>A p.R2371K | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGHV3-13 | chr14:106129526 TTCCCCTCACTGTGTCTCTTGCACAGTAATACACA>CGGTGACAG | Missense Mutation (DEL) | VAF 63/73 reads (86%) | called by pindel, varscan2*
- IL1RL1 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MED23 | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 20/325 reads (6%) | called by muse, mutect2
- MED23 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 233/493 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PDXDC1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 26/938 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); called by muse, mutect2
- PLEKHM3 | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 41/502 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- SLITRK3 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TPST1 | c.846-1G>C p.X282_splice | Splice Site (SNP) | VAF 108/238 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.12496G>C p.E4166Q (on ENST00000591111; = p.E4120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 122/305 reads (40%) | called by muse, mutect2, varscan2
- ZNF281 | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 44/545 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2
- JPH1 | c.879C>T p.F293= | Silent (SNP) | VAF 235/508 reads (46%) | catalogued as COSV60608312; called by muse, mutect2, varscan2
- KCNJ15 | c.792G>A p.L264= | Silent (SNP) | VAF 33/510 reads (6%) | catalogued as COSV100154097, COSV60810374; called by muse, mutect2
- MN1 | c.2754C>G p.L918= | Silent (SNP) | VAF 312/705 reads (44%) | called by muse, mutect2, varscan2
- NYNRIN | c.3276C>T p.T1092= | Silent (SNP) | VAF 243/524 reads (46%) | catalogued as rs371702363; called by muse, mutect2, varscan2
- OR52B2 | c.210C>T p.V70= | Silent (SNP) | VAF 201/423 reads (48%) | catalogued as rs753558772; called by muse, mutect2, varscan2
- PLBD1 | c.642C>T p.N214= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs200233914, COSV53696591; called by muse, mutect2, varscan2
- ROS1 | c.1602G>C p.L534= | Silent (SNP) | VAF 29/255 reads (11%) | called by muse, mutect2, varscan2
- SPECC1 | c.171C>T p.D57= | Silent (SNP) | VAF 197/387 reads (51%) | called by muse, mutect2, varscan2
- ZFP91 | c.1281C>T p.F427= | Silent (SNP) | VAF 26/398 reads (7%) | called by muse, mutect2
- CORO1C | c.-2C>T | 5'UTR (SNP) | VAF 24/270 reads (9%) | catalogued as rs768486704, COSV54599633; called by muse, mutect2
- CSH1 | c.457-124C>T | Intron (SNP) | VAF 183/494 reads (37%) | catalogued as rs945517620, COSV60241939, COSV60242986; called by muse, mutect2, varscan2
- FAM13B | c.-127C>G | 5'UTR (SNP) | VAF 129/329 reads (39%) | called by muse, mutect2, varscan2
- IRF2 | chr4:184475085 G>A | 5'Flank (SNP) | VAF 13/415 reads (3%) | called by muse, mutect2
- JMJD4 | c.693-82C>T | Intron (SNP) | VAF 58/702 reads (8%) | called by muse, mutect2
- PRB1 | c.101-1497T>G | Intron (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
